BEATAML1.0 case 2269 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/44807890-2c31-4730-8e8e-0a3d9c6d4738

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Acute myeloid leukemia with t(6;9)(p23;q34), DEK-NUP214: ICD-O-3 morphology code: 9865/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.9 years (4,335 days); Progression or recurrence: yes; ELN risk classification: Adverse.

Biospecimens (1 sample)
- Sample BA2922R: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Fresh.
